CMI case ASCProject_0097 — CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/add4ef41-8d14-4169-8ebb-9aadfc71b407

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Angiosarcoma: Tissue or organ of origin: Head, face or neck, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 38.5 years (14,044 days).

Biospecimens (4 samples)
- Sample ASCProject_0097_SALIVA_2: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Samples ASCProject_0097_T2_WES, ASCProject_0097_T3_WES (2 with the same recorded description): Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Neck; Preservation method: FFPE.
- Sample ASCProject_0097_T4_WES: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Chin; Preservation method: FFPE.
